CCDI case PBCBSI — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Cervix uteri.
https://portal.gdc.cancer.gov/cases/05c5bee0-7de1-4a3a-8fd0-d53b98cc7f52

Demographics
Sex at birth: female; Race: american indian or alaska native.

Diagnoses (1)
1. Undifferentiated sarcoma: ICD-O-3 morphology code: 8805/3; Tissue or organ of origin: Endocervix; Age at diagnosis: 22.0 years (8,038 days).

Biospecimens (3 samples)
- Sample 0DNKZC: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DNKZF: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DNKZM: Tissue type: Tumor; Specimen type: Solid Tissue.
